Gene-level copy-number profile of tumor specimen ALCH-B35L-TTP1-A from ALCHEMIST case ALCH-B35L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.3 years (26,421 days).
Specimen ALCH-B35L-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ed1cdeae-a6d2-43c3-88f0-c5871a59cbea.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B35L-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/4224bfa9-e450-4982-a5c5-3bde65922898

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 146; copy number 2: 14,690; copy number 3: 16,875; copy number 4: 20,051; copy number 5: 4,959; copy number 6: 719; copy number 7: 772; copy number 8: 25; copy number 9: 49; copy number 10: 1; copy number 11: 92; copy number 13: 5; copy number 25: 2.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,201,647–87,342,612, 4 genes: NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A.
- chr11:4,954,772–4,955,713, 1 gene (within-gene range 0–3): OR51A2.
- chr11:55,602,360–55,652,854, 3 genes: OR4C11, OR4P4, OR4S2.
- chr19:6,361,531–6,370,242, 1 gene (within-gene range 0–2): CLPP.
- chr19:20,432,552–20,571,095, 2 genes (within-gene range 0–2): AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 149 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,748,087–87,825,952, 3 genes, copy number 9–25: PLGLB2, RGPD2, MTATP8P2.
- chr2:137,715,332–138,902,747, 17 genes, copy number 9–10: Y_RNA, HNMT, LINC01832, RPL15P5, YWHAEP5, IDI1P1, RNF14P1, AC114763.1, AC114763.2, SPOPL, AC092620.1, AC092620.2, LINC02631, NXPH2, RN7SKP286, YY1P2, AHCYP4.
- chr2:164,492,417–164,843,679, 5 genes, copy number 13 (within-gene range 7–13): GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F.
- chr6:35,342,558–40,587,364, 117 genes, copy number 9–11 (broad region; genes not listed).
- chr16:35,021,749–35,085,060, 5 genes, copy number 9 (within-gene range 1–9): AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11.
- chr22:18,873,543–18,894,407, 2 genes, copy number 9: FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 136. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
